Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A6B1, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A6B1-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

[Redacted]
[Redacted]
[Redacted] (Age: [Redacted])
M
[Redacted]
[Redacted]
[Redacted]

Location:

Service: Urology

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

[Redacted]

INPATIENT

Clinical Diagnosis & History:

year old male with newly diagnosed bladder carcinoma.

Specimens Submitted:

- 1: Bladder, prostate, seminal vesicles, cytoprostatectomy
- 2: Soft tissue, left pelvic, resection
- 3: Lymph nodes, right pelvic, resection:
- 4: SP: Left pelvic lymph nodes #2
- 5: SP: Distal margin of urethra
- 6: SP: Pelvic floor
- 7: SP: Distal left ureter
- 8: SP: Distal right ureter

*ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site: Bladder, anterior wall
C67.3
Op 6/18/13*

DIAGNOSIS:

1. Bladder, prostate, seminal vesicles, cytoprostatectomy:

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Papillary and flat

Pattern of growth of the Invasive component:

Inverted / Nodular

Tumor Multicentricity:

Identified

The intervening urothelium is also involved by carcinoma.

Bladder Local Invasion:

Superficial half of muscularis propria

Extravesical Tumor Extension:

Right ureter uninvolved

Left ureter uninvolved

Urethra uninvolved

Vascular Invasion:

Not identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

See part 5, 7, and 8 for the urethral and ureteral margins.

Non-Neoplastic Mucosa:
Unremarkable

Prostate:
Nodular hyperplasia
Other High-grade prostatic intraepithelial neoplasia

Seminal Vesicles:
Not involved

Perivesical Lymph Nodes:
Not identified

The Pathologic Stage is (AJCC, 2002):
pT2a (Invades superficial half of muscularis propria)
PR0 (No involvement of prostate)

2. Soft tissue, left pelvic, resection:

Fibroadipose tissue negative for tumor.

3. Lymph nodes, right pelvic, resection::

Lymph Nodes:
Not involved
Number of nodes examined: 3

4. Soft tissue, left pelvic "lymph nodes #2", resection:

Fibroadipose tissue negative for tumor.

5. Urethra, distal margin, resection:

Segment of urethra and prostatic tissue negative for tumor.

6. Soft tissue, pelvic floor, resection:

Prostatic tissue negative for tumor.

7. Ureter, left distal, resection:

Segment of ureter negative for tumor.

8. Ureter, right distal, resection:

Segment of ureter negative for tumor.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "Cystoprostatectomy". It consists of a urinary bladder, prostate, urachus, perivesical soft tissues, seminal vesicles and lymph nodes with bladder totally measuring 12.1 cm from superior to inferior, 12.6 cm laterally and 4.5 cm from anterior to posterior. The bladder measures 7.5 x 7.1 x 4.1 cm, the prostate measures 5.6 x 3.9 x 3.6 cm, the right seminal vesicle measures 3.5 x 2.0 x 1.0 cm, the right vas deferens measures 6.8 x 0.3 x 0.3 cm, the left seminal vesicle measures 4.3 x 1.4 x 1.0 cm and the left vas deferens measures 7.2 x 0.3 x 0.3 cm. The anterior aspect of the bladder is inked blue and the posterior black. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

midline to reveal a fungating, nodular and papillary mass measuring 7.1 x 6.4 x 3.1 cm which is situated within the anterior wall and extending to involve the bladder dome. The lesion measures 0.6 cm from the left orifice and 0.8 cm from the right. Both ureters are probe patent measuring up to 0.2 cm in maximum diameter with the right ureter 4.6 cm long and left ureter 5.5 cm long. The lesion is sectioned to reveal involvement of the bladder wall. Extension to the inked fat is grossly not identified. An additional papillary lesion is noted on the right posterior wall, close to the prostatic urethra, 1.2 cm from the right ureteric orifice and measuring 1.2 x 0.7 x 0.4 cm. The remaining bladder mucosa is congested. Discrete perivesical lymph nodes are grossly not identified. The prostate is serially sectioned to reveal multiple nodules ranging from 0.2 to 0.5 cm located periurethrally. Representative sections are submitted including three sections from each prostatic quadrant and transition zone. TPS is submitted.

Summary of sections:

UM -- urethral margin
RUM-- right ureter margin.
LUM -- left ureter margin.
L-- lesion.
RUO -- right ureter orifice.
LUO-- left ureter orifice.
LP -- left posterior wall.
LA -- left anterior wall.
RP -- right posterior wall.
RA-- right anterior wall.
TRI -- trigone.
DOM-- dome.
RSV -- right seminal vesicle
LSV -- left seminal vesicle
RAP -- right apex prostate
LA P-- left apex prostate
RAM -- right anterior mid prostate
RPM -- right posterior mid prostate
LAM -- left anterior mid prostate
LPM -- left posterior mid prostate
RAB -- right anterior base prostate
RPB -- right posterior base prostate
LAB -- left anterior base prostate
LPB -- left posterior base prostate
UR -- urachus

2). The specimen is received fresh, labeled "left pelvic lymph nodes" and consists of multiple yellow lobulated tissue fragments aggregating 5.1 x 2.0 x 0.3 cm in greatest dimension. No definite lymph nodes are identified. Tissue entirely submitted.

Summary of sections:

LN -- lymph nodes

3). The specimen is received fresh, labeled "right pelvic lymph" and consists of multiple pink-tan firm lymph nodes ranging from 0.3 to 1.4 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph nodes

4). The specimen is received fresh, labeled "left pelvic lymph nodes number two" and consists of multiple pink-tan firm lymph nodes ranging from 0.7 to 1.9 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph node

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

5). The specimen is received in formalin, labeled "distal margin of urethra" and consists of a 1.5 x 0.9 x 0.7 cm red-tan, irregular unoriented soft tissue fragment. Serially sectioned and entirely submitted.

Summary of sections:
U-undesignated

6). The specimen is received in formalin, labeled "pelvic floor" and consists of a 1.2 x 0.7 x 0.7 cm red-tan soft tissue fragment. Entirely submitted.

Summary of sections:
U-undesignated

7). The specimen is received in formalin in, labeled "distal left ureter" and consists of a red-tan tubular structure, 0.6 cm in length by 0.4 cm in diameter. Section and entirely submitted.

Summary of sections:
U-undesignated

8). The specimen is received in formalin, labeled "distal right ureter, clip on proximal margin" and consists of a gray-white tubular structure and surrounding adipose tissue. The tubular structure measures 1.5 cm in length by 0.3 cm in diameter, and a clip marks the proximal margin, which is submitted separately. The remaining of the ureter is serially sectioned and entirely submitted.

Summary of sections
PM - proximal margin
R - remaining ureter

Summary of Sections:

Part 1: Bladder, prostate, seminal vesicles, cytoprostectomy

Block	Sect. Site	PCs
1	DOM	1
11	L	11
1	LA	1
1	LAB	1
1	LAM	1
1	LAP	1
1	LP	1
1	LPB	1
1	LPM	1
1	LSV	1
1	LUM	1
1	LUO	1
2	RA	2
1	RAB	1
1	RAM	1
1	RAP	1
2	RP	2
1	RPB	1
1	RPM	1
1	RSV	1
1	RUM	1

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

1	RUO	1
1	TRI	1
1	UM	1
1	UR	1

Part 2: Soft tissue, left pelvic, resection

Block	Sect. Site	PCs
4	LN	4

Part 3: Lymph nodes, right pelvic, resection:

Block	Sect. Site	PCs
2	BLN	2
2	LN	2

Part 4: SP: Left pelvic lymph nodes #2

Block	Sect. Site	PCs
1	bln	1
2	ln	2

Part 5: SP: Distal margin of urethra

Block	Sect. Site	PCs
1	u	1

Part 6: SP: Pelvic floor

Block	Sect. Site	PCs
1	u	1

Part 7: SP: Distal left ureter

Block	Sect. Site	PCs
1	u	1

Part 8: SP: Distal right ureter

Block	Sect. Site	PCs
1	pm	1
1	r	1

Not Malignancy History	PTI bladder	✓
Metastatic/Synchronous Primary Noted		✓

Source: NCI Genomic Data Commons file 8fbde43c-c850-48ad-b28f-b1a5441ee9f9 (TCGA-DK-A6B1.D475F198-6FFF-4869-922E-5E0F5BC564C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).